Surgical pathology report (de-identified scan), TCGA case TCGA-44-A4SS, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-44-A4SS-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

A. Lung, left upper lobe, resection: Moderately differentiated adenocarcinoma. Pulmonary emphysema.

B. Lymph node, 4L, biopsy: A single lymph node is negative for malignancy.

C. Lymph node, level VII, biopsy: There is no evidence of malignancy in any of 3 lymph nodes

D. Lymph node, level IX, biopsy: A single lymph node is negative for malignancy.

E. Lymph node, level V, biopsy: There is no evidence of malignancy in any of 7 lymph node pieces.

F. Lymph node, level XI, biopsy: A single lymph node is negative for malignancy

G. Lymph node, level XII, biopsy: A single lymph node is negative for malignancy.

Microscopic Description:

A.

Histologic type: Adenocarcinoma with eosinophilic cytoplasm

Histologic grade: 2

Mitotic index: 17 mitoses/10 HPFs (1 HPF = 0.23 sq. mm)

Tumor size: 2.5 cm

Bronchial resection margin: Negative for malignancy

Pleura: Negative for malignancy

Vascular invasion: Focal histologic features adjacent to the tumor compatible with vascular invasion

Attached lymph nodes: There is no evidence of malignancy in any 10 hilar lymph nodes

pTNM stage: T1

Non-tumorous lung: Emphysema

Specimen

A. Left upper lobe

B. 4L. lymph node

C. Level 7 lymph node

D. Level 9 lymph node

E. Level 5 lymph node

F. Level 11 lymph node

G. Level 12 lymph node

ICD-0-3

adenocarcinoma, NOS 8140/3

Site: lung, upper lobe c34.1

lw

10/27/12

Clinical Information

Left upper lobe lesion, lung cancer, tobacco abuse, alcohol abuse

Intraoperative Consultation

A. Lung, left upper lobe, resection: Positive for carcinoma. No carcinoma seen in tissue at bronchial margin.

[page 2 of 2]
Gross Description

Specimen A. is received labeled left upper lobe lung lobe measuring 26 by 14 by 6 cm there is a palpable mass with some overlying puckering of pleura that is 5.5 cm from the bronchial margin. On cut section the mass is white and measures 2.5 cm in diameter there is an area of red discoloration of lung at one side of the specimen this area measures 1.7 cm in greatest dimension. A portion of the tumor is taken for frozen section diagnosis. The bronchial margin is also taken for frozen section diagnosis. Sections after fixation.

Specimen B. is received unfixed labeled 4L. lymph node and consists of a piece of dark colored soft tissue measuring 0.6 cm in greatest dimension.

Specimen C. is received unfixed labeled level VII lymph node and consists of multiple pieces of dark soft tissue measuring 2 cm in greatest aggregate dimension.

Specimen D. is received unfixed labeled level IX lymph node and consists of a piece of dark colored soft tissue measuring 0.4 cm in greatest dimension.

Specimen E. is received unfixed labeled level V lymph node and consists of multiple pieces of dark soft tissue measuring 2 cm in greatest aggregate dimension.

Specimen F. is received unfixed labeled level XI lymph node and consists of a piece of dark soft tissue measuring 0.7 cm in greatest dimension.

Specimen G. is received unfixed labeled level XII lymph node and consists of a piece of dark soft tissue measuring 0.3 cm in greatest dimension.

Dual/Synchronous Pathology Noted		

10/27/12

Source: NCI Genomic Data Commons file 8999c3d9-d3fa-4ff5-a346-dd0593fca361 (TCGA-44-A4SS.12F30C5F-91F0-4ECD-A073-74CDEA147097.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).